Somatic mutation profile of cancer-model specimen HCM-BROD-0220-C15-85D (Adherent Cell Line, passage 8; aliquot HCM-BROD-0220-C15-85D-01D-A87L-36), derived from the metastatic tumor of HCMI case HCM-BROD-0220-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: GX; Age at diagnosis: 60.2 years (21,985 days).
Specimen HCM-BROD-0220-C15-85D: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4a57508-baa4-4c8e-b675-32e30d0eadbf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0220-C15-10A (Blood Derived Normal), aliquot HCM-BROD-0220-C15-10A-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/965969a9-1df9-44ec-8a96-0f2ccdd59584

The open-access MAF lists 227 somatic variants for this specimen: 165 protein-altering or splice-affecting, 54 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 149, Silent 54, Nonsense Mutation 7, Frame Shift Del 5, Intron 3, Frame Shift Ins 2, 5'Flank 2, 3'Flank 1, In Frame Del 1, 3'UTR 1, IGR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.9097del p.T3033Lfs*29 | Frame Shift Del (DEL) | VAF 44/334 reads (13%) | catalogued as rs397507419; ClinVar: not provided / pathogenic; called by mutect2, varscan2
- CDKN2A | c.83_100del p.V28_E33del | In Frame Del (DEL) | VAF 87/319 reads (27%) | hotspot (GDC flag); called by pindel, varscan2
- TP53 | c.820G>T p.V274F | Missense Mutation (SNP) | VAF 319/413 reads (77%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); catalogued as rs1057520005, COSV52707923, COSV52708386, COSV52728497, COSV53727597; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC4 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 95/507 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV65313251; called by muse, mutect2, varscan2
- ADAM18 | c.1466A>G p.Y489C | Missense Mutation (SNP) | VAF 64/441 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs142229705; called by muse, mutect2, varscan2
- ADAM29 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 98/263 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs765339011, COSV63660350; called by muse, mutect2, varscan2
- ADAM30 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 212/325 reads (65%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.915); catalogued as rs200088734, COSV65561660; called by muse, mutect2, varscan2
- ADAMTS3 | c.3439G>A p.V1147I | Missense Mutation (SNP) | VAF 104/321 reads (32%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as rs759487867, COSV54390590; called by muse, mutect2, varscan2
- ADCY2 | c.2656G>A p.V886I | Missense Mutation (SNP) | VAF 171/462 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as rs326146, COSV57901415; called by muse, mutect2, varscan2
- ANKRD30B | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 47/204 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as rs761682028, COSV100746671; called by muse, mutect2, varscan2
- ANO4 | c.2393G>C p.R798P (on ENST00000392977 / NM_001286615.2; = p.R763P on NM_178826.4) | Missense Mutation (SNP) | VAF 23/430 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54594322; called by muse, mutect2
- AP002512.3 | c.367C>A p.R123S | Missense Mutation (SNP) | VAF 136/586 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.421); catalogued as rs772474039, COSV54406603; called by muse, mutect2, varscan2
- ARID3A | c.631G>A p.V211I | Missense Mutation (SNP) | VAF 174/516 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as rs577924521; called by muse, mutect2, varscan2
- ASIC5 | c.440A>T p.N147I | Missense Mutation (SNP) | VAF 153/361 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as COSV101539702; called by muse, mutect2, varscan2
- AXL | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 201/506 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs1306116384, COSV56568438; called by muse, mutect2, varscan2
- C10orf71 | c.4112G>A p.R1371H | Missense Mutation (SNP) | VAF 142/540 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs576453887, COSV60511789; called by muse, mutect2, varscan2
- C11orf87 | c.182C>T p.T61M | Missense Mutation (SNP) | VAF 133/587 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs187108020, COSV59356856; called by muse, mutect2, varscan2
- CCER1 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 167/616 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.305); catalogued as COSV62646847; called by muse, varscan2
- CDHR4 | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 39/364 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as rs372946545; called by muse, mutect2, varscan2
- CEP170 | c.4184C>A p.P1395H | Missense Mutation (SNP) | VAF 20/640 reads (3%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.797); catalogued as rs201404435; called by muse, mutect2
- CLDN8 | c.25G>T p.A9S | Missense Mutation (SNP) | VAF 25/297 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.614); catalogued as rs778908212, COSV54527935; called by muse, mutect2
- COL24A1 | c.4230del p.D1412Mfs*28 | Frame Shift Del (DEL) | VAF 72/233 reads (31%) | catalogued as COSV65302287; called by mutect2, pindel, varscan2
- CWC22 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 86/325 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.758); catalogued as rs1306263212; called by muse, mutect2, varscan2
- DNAH9 | c.5020G>A p.G1674R | Missense Mutation (SNP) | VAF 37/272 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140721719, COSV52363260, COSV52364084; called by muse, mutect2, varscan2
- DTL | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 42/514 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765518413; called by muse, mutect2
- DYTN | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 86/421 reads (20%) | catalogued as COSV65970515; called by muse, mutect2, varscan2
- EZHIP | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 15/360 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.051); catalogued as COSV57956911, COSV57957472; called by muse, mutect2
- FARSB | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 133/302 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs767956337, COSV56051949; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- FBRSL1 | c.1675C>T p.R559W | Missense Mutation (SNP) | VAF 234/469 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1287979091; called by muse, mutect2, varscan2
- FBXL20 | c.1211T>C p.L404S | Missense Mutation (SNP) | VAF 1204/4221 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.303); catalogued as COSV99060050; called by muse, mutect2, varscan2
- GIMAP4 | c.146G>C p.S49T | Missense Mutation (SNP) | VAF 99/444 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.216); catalogued as rs1428397783; called by muse, mutect2, varscan2
- GRIK1 | c.464C>A p.A155E | Missense Mutation (SNP) | VAF 70/243 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.232); catalogued as rs1177067242, COSV58711534; called by muse, mutect2, varscan2
- GTF2E1 | c.7G>C p.D3H | Missense Mutation (SNP) | VAF 17/210 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs150809090; called by muse, mutect2
- IKZF1 | c.33A>C p.Q11H | Missense Mutation (SNP) | VAF 84/608 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.172); catalogued as rs1480100906; called by muse, mutect2, varscan2
- JAK1 | c.1798G>T p.G600W | Missense Mutation (SNP) | VAF 134/371 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61096327; called by muse, mutect2, varscan2
- KCNA6 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 139/629 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV99768939; called by muse, mutect2, varscan2
- KIAA1109 | c.1604C>T p.A535V | Missense Mutation (SNP) | VAF 49/202 reads (24%) | SIFT tolerated (1); PolyPhen probably damaging (0.985); catalogued as rs1291063022; called by muse, mutect2, varscan2
- KIF1A | c.2650C>T p.R884C | Missense Mutation (SNP) | VAF 50/214 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs760325615, COSV57491717; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KRT17 | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 172/2370 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as rs755542251; called by muse, mutect2
- L3MBTL1 | c.605C>A p.P202Q (on ENST00000418998 / NM_001377303.1; = p.P112Q on NM_015478.7) | Missense Mutation (SNP) | VAF 91/632 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.359); catalogued as COSV64233573; called by muse, mutect2, varscan2
- LAMA1 | c.2266G>A p.V756I | Missense Mutation (SNP) | VAF 88/351 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.026); catalogued as rs776368738, COSV67541780; called by muse, mutect2, varscan2
- LAMA1 | c.1745C>T p.A582V | Missense Mutation (SNP) | VAF 218/407 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as rs780440007, COSV67531188; called by muse, mutect2, varscan2
- LBX2 | c.535G>A p.G179S (on ENST00000377566 / NM_001282430.2; = p.G175S on NM_001009812.2) | Missense Mutation (SNP) | VAF 250/475 reads (53%) | SIFT tolerated (0.75); PolyPhen benign (0.019); catalogued as rs777056738; called by muse, mutect2, varscan2
- LILRB4 | c.601T>G p.F201V | Missense Mutation (SNP) | VAF 101/393 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as COSV54409361; called by muse, mutect2, varscan2
- LRIT1 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 114/473 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.12); catalogued as COSV100928200; called by muse, mutect2, varscan2
- LRRN4 | c.2146C>T p.R716C | Missense Mutation (SNP) | VAF 43/530 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs756574056; called by muse, mutect2
- MAST2 | c.4463G>A p.R1488Q | Missense Mutation (SNP) | VAF 23/409 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs759548390; called by muse, mutect2
- MYRF | c.316G>A p.G106S (on ENST00000278836 / NM_001127392.3; = p.G97S on NM_013279.4) | Missense Mutation (SNP) | VAF 164/737 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as rs143154821; called by muse, mutect2, varscan2
- NEO1 | c.2327G>A p.G776D | Missense Mutation (SNP) | VAF 91/367 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1567628993; called by muse, mutect2, varscan2
- OR10R2 | c.241T>G p.F81V | Missense Mutation (SNP) | VAF 103/428 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs1008730168; called by muse, mutect2, varscan2
- OR8U1 | c.94T>G p.L32V | Missense Mutation (SNP) | VAF 90/473 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as rs1384529091, COSV56414040, COSV56416675; called by muse, varscan2
- PHIP | c.499A>G p.T167A | Missense Mutation (SNP) | VAF 110/340 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.344); catalogued as rs748247534; called by muse, mutect2, varscan2
- PPP1R32 | c.424G>C p.A142P | Missense Mutation (SNP) | VAF 54/500 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV58545900; called by muse, mutect2, varscan2
- PTK2B | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 122/310 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs765936240; called by muse, mutect2, varscan2
- RYR2 | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 145/396 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.145); catalogued as COSV63683406; called by muse, mutect2, varscan2
- SEMA6D | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 61/236 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs764064628; called by muse, mutect2, varscan2
- SLITRK4 | c.701A>C p.N234T | Missense Mutation (SNP) | VAF 98/272 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV100567598; called by muse, mutect2, varscan2
- TBPL2 | c.427G>A p.G143R | Missense Mutation (SNP) | VAF 132/379 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs368981752; called by muse, mutect2, varscan2
- TCERG1 | c.1985G>A p.R662Q | Missense Mutation (SNP) | VAF 83/343 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1303714163; called by muse, mutect2, varscan2
- TRIM2 | c.1582C>T p.R528C (on ENST00000437508; = p.R555C on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 85/280 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58635738; called by muse, mutect2, varscan2
- VN1R4 | c.160T>C p.F54L | Missense Mutation (SNP) | VAF 97/252 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as COSV60805387; called by muse, mutect2, varscan2
- XKR4 | c.1766G>A p.R589Q | Missense Mutation (SNP) | VAF 48/698 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.974); catalogued as rs1392195420, COSV59340976; called by muse, mutect2
- ZBTB46 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 83/553 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs568344981; called by muse, mutect2, varscan2
- ZFHX4 | c.872G>T p.R291M | Missense Mutation (SNP) | VAF 239/544 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50620924; called by muse, mutect2, varscan2
- ABCA13 | c.13078C>G p.P4360A | Missense Mutation (SNP) | VAF 28/580 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.034); called by muse, mutect2
- ABCA9 | c.3665G>T p.C1222F | Missense Mutation (SNP) | VAF 70/191 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ADA2 | c.452C>A p.P151Q | Missense Mutation (SNP) | VAF 116/335 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ALAS2 | c.1514A>T p.N505I | Missense Mutation (SNP) | VAF 66/414 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD13B | c.1339C>T p.R447* | Nonsense Mutation (SNP) | VAF 53/355 reads (15%) | called by muse, mutect2, varscan2
- ARHGAP15 | c.598A>T p.R200* | Nonsense Mutation (SNP) | VAF 48/152 reads (32%) | called by muse, mutect2, varscan2
- C5orf38 | c.164G>T p.G55V | Missense Mutation (SNP) | VAF 294/787 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- C6orf226 | c.230T>A p.I77K | Missense Mutation (SNP) | VAF 156/557 reads (28%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- CADM1 | c.793T>G p.L265V | Missense Mutation (SNP) | VAF 88/339 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAPN6 | c.1876G>T p.G626C | Missense Mutation (SNP) | VAF 107/314 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CARS2 | c.1273G>A p.G425S | Missense Mutation (SNP) | VAF 156/650 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC107 | c.812C>G p.T271R | Missense Mutation (SNP) | VAF 94/246 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CD8A | c.452C>A p.T151N | Missense Mutation (SNP) | VAF 122/493 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- CDKN2A | c.37_40dup p.D14Gfs*2 | Nonsense Mutation (INS) | VAF 110/304 reads (36%) | called by pindel, varscan2
- CDRT1 | c.1847A>C p.K616T | Missense Mutation (SNP) | VAF 97/347 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- CENPJ | c.2602A>C p.K868Q | Missense Mutation (SNP) | VAF 76/365 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- CHD4 | c.773G>C p.R258P | Missense Mutation (SNP) | VAF 70/299 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- CNGA2 | c.166G>C p.V56L | Missense Mutation (SNP) | VAF 11/389 reads (3%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); called by muse, mutect2
- CNTN1 | c.943A>G p.I315V | Missense Mutation (SNP) | VAF 20/281 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2
- COBLL1 | c.2784A>T p.K928N (on ENST00000392717; = p.K890N on NM_014900.5) | Missense Mutation (SNP) | VAF 40/259 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- COL6A6 | c.4201G>A p.G1401R | Missense Mutation (SNP) | VAF 102/257 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPT1A | c.1421C>T p.S474F | Missense Mutation (SNP) | VAF 92/450 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CYSRT1 | c.445G>A p.G149R (on ENST00000409414; = p.G109R on NM_199001.5) | Missense Mutation (SNP) | VAF 192/589 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- DCDC1 | c.2456A>C p.N819T | Missense Mutation (SNP) | VAF 70/317 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DCHS1 | c.6041A>G p.D2014G | Missense Mutation (SNP) | VAF 231/494 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- DNAH9 | c.10651C>A p.L3551I | Missense Mutation (SNP) | VAF 95/382 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- DST | c.5331T>G p.S1777R | Missense Mutation (SNP) | VAF 59/401 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- DST | c.1432A>C p.N478H (on ENST00000361203 / NM_001374722.1; = p.N152H on NM_001723.6) | Missense Mutation (SNP) | VAF 95/398 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- EEF1AKNMT | c.1979T>A p.L660H (on ENST00000361735 / NM_015935.5; = p.L574H on NM_014955.3) | Missense Mutation (SNP) | VAF 120/531 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EHMT2 | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 16/496 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- ELP4 | c.186_207del p.V63* | Frame Shift Del (DEL) | VAF 68/373 reads (18%) | called by mutect2, pindel, varscan2
- EPHA6 | c.2794dup p.I932Nfs*45 | Frame Shift Ins (INS) | VAF 71/236 reads (30%) | called by mutect2, pindel, varscan2
- ERVV-1 | c.644C>G p.P215R | Missense Mutation (SNP) | VAF 64/436 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- FAM135B | c.2900C>G p.A967G | Missense Mutation (SNP) | VAF 194/654 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM83H | c.293_318del p.V98Afs*2 | Frame Shift Del (DEL) | VAF 323/1245 reads (26%) | called by mutect2, pindel, varscan2
- FASN | c.5558T>A p.V1853D | Missense Mutation (SNP) | VAF 101/260 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- GALNT14 | c.615C>A p.N205K | Missense Mutation (SNP) | VAF 75/382 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GIMAP2 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 109/497 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- GNAS | c.473C>A p.P158Q | Missense Mutation (SNP) | VAF 70/726 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.909); called by muse, mutect2
- GPM6A | c.608A>T p.E203V | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- GYPB | c.131C>G p.T44R | Missense Mutation (SNP) | VAF 140/328 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- HAPLN2 | c.431G>A p.S144N | Missense Mutation (SNP) | VAF 70/284 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HOOK2 | c.589C>A p.L197M | Missense Mutation (SNP) | VAF 84/254 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HOXA13 | c.503C>A p.A168E | Missense Mutation (SNP) | VAF 258/2313 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); called by muse, varscan2
- IFNLR1 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 46/375 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- IGKV3D-11 | c.303A>C p.E101D | Missense Mutation (SNP) | VAF 93/405 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- ILDR2 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 168/591 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- INO80 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 144/335 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- KCNK2 | c.793A>C p.T265P (on ENST00000444842 / NM_001017425.3; = p.T250P on NM_014217.4) | Missense Mutation (SNP) | VAF 93/319 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNN2 | c.1585A>G p.S529G (on ENST00000264773; = p.S741G on NM_021614.4) | Missense Mutation (SNP) | VAF 97/344 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- KCNT2 | c.164dup p.N55Kfs*37 | Frame Shift Ins (INS) | VAF 6/35 reads (17%) | called by mutect2, pindel, varscan2
- KLRD1 | c.337C>A p.Q113K | Missense Mutation (SNP) | VAF 76/317 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KRT9 | c.1390G>A p.D464N | Missense Mutation (SNP) | VAF 126/1640 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- KRTAP10-8 | c.280T>A p.C94S | Missense Mutation (SNP) | VAF 107/400 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- KRTAP29-1 | c.965G>T p.C322F | Missense Mutation (SNP) | VAF 324/5280 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); called by muse, mutect2
- L3MBTL1 | c.604C>T p.P202S (on ENST00000418998 / NM_001377303.1; = p.P112S on NM_015478.7) | Missense Mutation (SNP) | VAF 90/633 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- LARP1 | c.784G>A p.E262K (on ENST00000518297 / NM_033551.3; = p.E185K on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 84/354 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.079); called by muse, varscan2
- LILRB4 | c.319T>C p.S107P | Missense Mutation (SNP) | VAF 139/356 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LMCD1 | c.785C>A p.A262E | Missense Mutation (SNP) | VAF 123/393 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- LRCH1 | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 237/523 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MACROH2A1 | c.788G>A p.S263N (on ENST00000510038; = p.S262N on NM_004893.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/241 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- MAST1 | c.3220G>T p.A1074S | Missense Mutation (SNP) | VAF 91/272 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- MORC3 | c.1104-1G>C p.X368_splice | Splice Site (SNP) | VAF 25/98 reads (26%) | called by muse, mutect2, varscan2
- MSH4 | c.934del p.I312* | Frame Shift Del (DEL) | VAF 68/245 reads (28%) | called by mutect2, pindel, varscan2
- MTMR9 | c.1492T>C p.F498L | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- MUC16 | c.21310G>T p.A7104S | Missense Mutation (SNP) | VAF 30/357 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.196); called by muse, mutect2
- NCOR1 | c.3061G>T p.G1021C | Missense Mutation (SNP) | VAF 38/398 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.674); called by muse, mutect2
- NDUFAF3 | c.127C>A p.Q43K | Missense Mutation (SNP) | VAF 18/441 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.218); called by muse, mutect2
- NEUROD6 | c.428T>C p.I143T | Missense Mutation (SNP) | VAF 21/570 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- NKX6-2 | c.217G>A p.G73R | Missense Mutation (SNP) | VAF 152/530 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- NUP205 | c.5836C>G p.L1946V | Missense Mutation (SNP) | VAF 116/412 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OBSCN | c.22794C>G p.S7598R | Missense Mutation (SNP) | VAF 94/341 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- OR5B21 | c.103A>T p.I35F | Missense Mutation (SNP) | VAF 106/484 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OTOGL | c.6102T>A p.C2034* (on ENST00000547103; = p.C2025* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 75/287 reads (26%) | called by muse, mutect2, varscan2
- OXSM | c.305A>G p.N102S | Missense Mutation (SNP) | VAF 51/311 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCDH1 | c.2083C>T p.R695C | Missense Mutation (SNP) | VAF 52/436 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PGBD2 | c.1633A>G p.S545G | Missense Mutation (SNP) | VAF 104/527 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- PLCB3 | c.2456G>C p.G819A | Missense Mutation (SNP) | VAF 116/408 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PLEKHG3 | c.2285G>A p.W762* (on ENST00000394691; = p.W818* on NM_001308147.2) | Nonsense Mutation (SNP) | VAF 15/441 reads (3%) | called by muse, mutect2
- POMT1 | c.1062C>G p.N354K | Missense Mutation (SNP) | VAF 37/272 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- PPARG | c.896A>G p.Q299R (on ENST00000287820 / NM_015869.5; = p.Q269R on NM_005037.7) | Missense Mutation (SNP) | VAF 103/310 reads (33%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- PRSS56 | c.1234C>T p.Q412* | Nonsense Mutation (SNP) | VAF 52/588 reads (9%) | called by muse, mutect2
- PXN | c.1765C>T p.L589F (on ENST00000228307 / NM_001080855.3; = p.L555F on NM_002859.4) | Missense Mutation (SNP) | VAF 70/263 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RHBDD2 | c.100C>A p.P34T | Missense Mutation (SNP) | VAF 136/345 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RIMBP2 | c.2788T>C p.F930L | Missense Mutation (SNP) | VAF 56/305 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RUVBL2 | c.1307A>G p.E436G | Missense Mutation (SNP) | VAF 96/328 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- SBF2 | c.3040G>T p.A1014S | Missense Mutation (SNP) | VAF 108/479 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- SCGB1C1 | c.97T>G p.F33V | Missense Mutation (SNP) | VAF 84/471 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, varscan2
- SGCZ | c.794C>G p.S265C | Missense Mutation (SNP) | VAF 73/265 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- SLC12A9 | c.930C>A p.F310L | Missense Mutation (SNP) | VAF 109/350 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- SND1 | c.2548G>A p.D850N | Missense Mutation (SNP) | VAF 20/424 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); called by muse, mutect2
- SRCIN1 | c.2042G>T p.R681L (on ENST00000621492; = p.R647L on NM_025248.3) | Missense Mutation (SNP) | VAF 218/2712 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.058); called by muse, mutect2
- TASOR2 | c.5353T>G p.C1785G | Missense Mutation (SNP) | VAF 33/419 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2
- TCEAL5 | c.560T>G p.V187G | Missense Mutation (SNP) | VAF 162/472 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TENM1 | c.3592G>T p.V1198F | Missense Mutation (SNP) | VAF 230/296 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- TENM2 | c.4064T>A p.L1355Q (on ENST00000518659 / NM_001122679.2; = p.L1116Q on NM_001080428.3) | Missense Mutation (SNP) | VAF 55/258 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBAP2L | c.1996C>G p.L666V | Missense Mutation (SNP) | VAF 141/540 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- USF1 | c.431G>A p.G144D | Missense Mutation (SNP) | VAF 110/481 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ZBTB49 | c.291G>T p.M97I | Missense Mutation (SNP) | VAF 10/292 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); called by muse, mutect2
- ZNF433 | c.1994G>C p.G665A | Missense Mutation (SNP) | VAF 16/307 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- ZNF692 | c.56A>C p.Q19P | Missense Mutation (SNP) | VAF 173/815 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- ABCC5 | c.4071A>C p.T1357= | Silent (SNP) | VAF 160/300 reads (53%) | called by muse, mutect2, varscan2
- ADAM2 | c.2169C>T p.S723= | Silent (SNP) | VAF 51/203 reads (25%) | catalogued as rs751986797; called by muse, mutect2, varscan2
- AKR7A3 | c.690G>A p.E230= | Silent (SNP) | VAF 13/216 reads (6%) | called by muse, mutect2
- ATP7A | c.1440C>T p.D480= | Silent (SNP) | VAF 109/326 reads (33%) | called by muse, mutect2, varscan2
- BCL11A | c.270C>T p.I90= | Silent (SNP) | VAF 119/433 reads (27%) | catalogued as rs1446265434; called by muse, mutect2, varscan2
- C2CD6 | c.870A>G p.A290= | Silent (SNP) | VAF 38/421 reads (9%) | catalogued as rs764952063; called by muse, mutect2
- C5orf38 | c.165G>T p.G55= | Silent (SNP) | VAF 293/778 reads (38%) | called by muse, mutect2, varscan2
- C6 | c.1608G>T p.G536= | Silent (SNP) | VAF 103/789 reads (13%) | catalogued as rs1194069643; called by muse, mutect2, varscan2
- CALCRL | c.609C>A p.A203= | Silent (SNP) | VAF 102/229 reads (45%) | catalogued as COSV66476652; called by muse, mutect2, varscan2
- CASC3 | c.204C>T p.G68= | Silent (SNP) | VAF 130/1442 reads (9%) | called by muse, mutect2
- CBFA2T3 | c.111C>T p.A37= | Silent (SNP) | VAF 93/379 reads (25%) | catalogued as rs527797742, COSV51932421; called by muse, mutect2, varscan2
- CDK12 | c.3891G>T p.V1297= (on ENST00000447079 / NM_016507.4; = p.V1288= on NM_015083.3) | Silent (SNP) | VAF 257/8130 reads (3%) | called by muse, mutect2
- CDRT15L2 | c.300G>A p.A100= | Silent (SNP) | VAF 204/294 reads (69%) | catalogued as rs1266472474; called by muse, mutect2, varscan2
- CHL1 | c.1578C>T p.I526= (on ENST00000397491 / NM_001253387.1; = p.I542= on NM_006614.4) | Silent (SNP) | VAF 73/197 reads (37%) | catalogued as rs761187395, COSV56604120; called by muse, mutect2, varscan2
- DHH | c.618G>T p.V206= | Silent (SNP) | VAF 136/428 reads (32%) | called by mutect2, varscan2
- DMXL2 | c.3645T>G p.T1215= | Silent (SNP) | VAF 146/387 reads (38%) | catalogued as COSV51845749; called by muse, mutect2, varscan2
- DNAAF4 | c.1173G>C p.A391= | Silent (SNP) | VAF 68/202 reads (34%) | called by muse, mutect2, varscan2
- ETV3L | c.564A>G p.P188= | Silent (SNP) | VAF 85/366 reads (23%) | called by muse, mutect2, varscan2
- FAM181B | c.156G>A p.S52= | Silent (SNP) | VAF 127/572 reads (22%) | catalogued as rs1302146256, COSV100235094; called by muse, mutect2, varscan2
- FRA10AC1 | c.864A>G p.E288= | Silent (SNP) | VAF 148/331 reads (45%) | called by muse, mutect2, varscan2
- HERC1 | c.14415G>T p.L4805= | Silent (SNP) | VAF 45/205 reads (22%) | called by muse, mutect2, varscan2
- HHLA2 | c.258C>A p.P86= | Silent (SNP) | VAF 28/436 reads (6%) | catalogued as COSV63315956; called by muse, mutect2
- IFT140 | c.3912C>T p.H1304= | Silent (SNP) | VAF 125/385 reads (32%) | catalogued as rs143385994; called by muse, mutect2, varscan2
- IGSF10 | c.5085A>G p.K1695= | Silent (SNP) | VAF 15/345 reads (4%) | called by muse, mutect2
- IL12RB2 | c.2334G>A p.K778= | Silent (SNP) | VAF 291/435 reads (67%) | called by muse, mutect2, varscan2
- IL34 | c.57G>A p.L19= | Silent (SNP) | VAF 69/267 reads (26%) | called by muse, mutect2, varscan2
- IQCH | c.1125G>A p.K375= | Silent (SNP) | VAF 98/417 reads (24%) | called by muse, mutect2, varscan2
- ISM1 | c.1227G>A p.E409= | Silent (SNP) | VAF 175/617 reads (28%) | catalogued as rs761644256; called by muse, mutect2, varscan2
- KRT2 | c.1458C>T p.G486= | Silent (SNP) | VAF 15/132 reads (11%) | catalogued as rs769881626, COSV59009074, COSV59009927; called by muse, mutect2, varscan2
- LSS | c.54C>T p.P18= | Silent (SNP) | VAF 132/385 reads (34%) | called by muse, mutect2, varscan2
- MACF1 | c.14733G>A p.Q4911= (on ENST00000372915; = p.Q2844= on NM_012090.5) | Silent (SNP) | VAF 30/396 reads (8%) | catalogued as COSV57112653; called by muse, mutect2
- MFAP3 | c.522C>T p.S174= | Silent (SNP) | VAF 55/239 reads (23%) | catalogued as rs755554678; called by muse, varscan2
- NINL | c.4062C>T p.A1354= | Silent (SNP) | VAF 132/605 reads (22%) | catalogued as rs776524973; called by muse, mutect2, varscan2
- NOS2 | c.2730C>T p.I910= | Silent (SNP) | VAF 117/310 reads (38%) | called by muse, mutect2, varscan2
- OTOGL | c.2853C>T p.Y951= (on ENST00000547103; = p.Y942= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 74/310 reads (24%) | catalogued as rs770917728; called by muse, mutect2, varscan2
- PARD3 | c.39C>T p.V13= | Silent (SNP) | VAF 103/431 reads (24%) | catalogued as rs1241766266; called by muse, mutect2, varscan2
- PCDH11X | c.3630C>T p.S1210= | Silent (SNP) | VAF 183/429 reads (43%) | called by muse, mutect2, varscan2
- PCLO | c.6135G>T p.L2045= | Silent (SNP) | VAF 71/220 reads (32%) | catalogued as rs897450592; called by muse, mutect2, varscan2
- PGR | c.990C>T p.D330= | Silent (SNP) | VAF 106/456 reads (23%) | catalogued as COSV54805595; called by muse, varscan2
- PI15 | c.309T>C p.A103= | Silent (SNP) | VAF 138/591 reads (23%) | catalogued as COSV52640341; called by muse, mutect2, varscan2
- PIGK | c.1044A>G p.Q348= | Silent (SNP) | VAF 121/203 reads (60%) | catalogued as rs775599371, COSV63651061; called by muse, mutect2, varscan2
- PPFIA4 | c.3393C>T p.H1131= (on ENST00000447715; = p.H1132= on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 135/572 reads (24%) | catalogued as rs747437590; called by muse, mutect2, varscan2
- PPIL2 | c.1134T>G p.S378= | Silent (SNP) | VAF 84/261 reads (32%) | called by muse, mutect2, varscan2
- SLC9B1 | c.894T>A p.I298= | Silent (SNP) | VAF 77/245 reads (31%) | called by muse, mutect2, varscan2
- STARD9 | c.13482T>G p.T4494= | Silent (SNP) | VAF 50/180 reads (28%) | called by muse, mutect2, varscan2
- STAT5A | c.606G>A p.T202= | Silent (SNP) | VAF 74/313 reads (24%) | catalogued as rs375378402; called by muse, mutect2, varscan2
- TFAP2A | c.132C>T p.A44= (on ENST00000482890; = p.A36= on NM_001032280.3) | Silent (SNP) | VAF 60/325 reads (18%) | called by muse, mutect2, varscan2
- TNKS1BP1 | c.2709C>T p.N903= | Silent (SNP) | VAF 286/553 reads (52%) | catalogued as rs769313015, COSV64102562; called by muse, mutect2, varscan2
- USP17L1 | c.648T>G p.T216= | Silent (SNP) | VAF 123/392 reads (31%) | called by muse, mutect2, varscan2
- ZFHX4 | c.8847T>C p.S2949= | Silent (SNP) | VAF 192/512 reads (38%) | called by muse, mutect2, varscan2
- ZNF221 | c.492C>T p.H164= | Silent (SNP) | VAF 28/274 reads (10%) | catalogued as rs757802335; called by muse, mutect2, varscan2
- ZNF692 | c.57G>A p.Q19= | Silent (SNP) | VAF 172/816 reads (21%) | catalogued as rs771022929; called by muse, mutect2, varscan2
- ZNF726 | c.496A>C p.R166= | Silent (SNP) | VAF 63/193 reads (33%) | called by muse, mutect2, varscan2
- ZNF865 | c.609C>T p.C203= | Silent (SNP) | VAF 141/493 reads (29%) | catalogued as rs1220928798; called by muse, mutect2, varscan2
- C2orf16 | chr2:27571544 G>T | 5'Flank (SNP) | VAF 100/392 reads (26%) | called by muse, mutect2, varscan2
- CFAP46 | c.966+46A>G | Intron (SNP) | VAF 133/500 reads (27%) | called by muse, mutect2, varscan2
- CRY2 | chr11:45847262 C>T | 5'Flank (SNP) | VAF 31/700 reads (4%) | called by muse, mutect2
- KCNQ1 | c.1514+12839G>C | Intron (SNP) | VAF 165/296 reads (56%) | called by muse, mutect2, varscan2
- KIAA1328 | c.1523+20534C>A | Intron (SNP) | VAF 13/400 reads (3%) | called by muse, mutect2
- SLCO2A1 | chr3:133928661 G>T | 3'Flank (SNP) | VAF 112/356 reads (31%) | called by muse, mutect2, varscan2
- TRAF4 | c.*269T>G | 3'UTR (SNP) | VAF 106/284 reads (37%) | called by mutect2, varscan2
- Unknown | chr17:72592470 del CCGGGCGC | IGR (DEL) | VAF 47/365 reads (13%) | called by pindel, varscan2
